Somatic mutation profile of tumor specimen TCGA-XF-A9SK-01A (aliquot TCGA-XF-A9SK-01A-11D-A42E-08) from TCGA case TCGA-XF-A9SK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.8 years (24,019 days).
Specimen TCGA-XF-A9SK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b038c2a2-0137-4609-a26e-989f67085abe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SK-10A (Blood Derived Normal), aliquot TCGA-XF-A9SK-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8a2ed2a-d5e7-4cf1-8273-5f20b2acb170

The open-access MAF lists 162 somatic variants for this specimen: 125 protein-altering or splice-affecting, 29 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 29, Nonsense Mutation 10, Intron 3, 3'UTR 3, Frame Shift Del 2, In Frame Del 1, Splice Region 1, RNA 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.8053C>T p.R2685* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | hotspot (GDC flag); catalogued as rs587783727, COSV56420426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AARS1 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.215); catalogued as rs913427692, COSV55746040; called by muse, mutect2, varscan2
- ACSF2 | c.251G>A p.R84K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99366095; called by muse, mutect2
- ACTA1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64202843; called by muse, mutect2, varscan2
- ALMS1 | c.5227C>T p.Q1743* | Nonsense Mutation (SNP) | VAF 26/143 reads (18%) | catalogued as COSV52518366; called by muse, mutect2, varscan2
- ARID1B | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | catalogued as rs1554270802, COSV51686549; called by muse, mutect2, varscan2
- ASCC3 | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV61225687; called by muse, mutect2, varscan2
- ATL2 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV60050263; called by muse, mutect2, varscan2
- ATP10A | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63513196, COSV63517069; called by muse, mutect2, varscan2
- B4GALNT4 | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.127); catalogued as COSV57321406; called by muse, mutect2, varscan2
- BAZ2B | c.1773C>G p.F591L | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs1287760658, COSV58595326; called by muse, mutect2, varscan2
- BTRC | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV64560360; called by muse, mutect2, varscan2
- C5orf22 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256722028, COSV57597387; called by muse, mutect2, varscan2
- CAND1 | c.3125G>C p.R1042T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV73389518; called by muse, mutect2, varscan2
- CASP5 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52826532; called by muse, mutect2, varscan2
- CBLIF | c.1074-1G>C p.X358_splice | Splice Site (SNP) | VAF 14/52 reads (27%) | catalogued as rs1396850043, COSV57237908; called by muse, mutect2, varscan2
- CD44 | c.1501C>G p.L501V | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV53528011; called by muse, mutect2, varscan2
- CDCA3 | c.476C>A p.T159K | Missense Mutation (SNP) | VAF 82/137 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0.059); catalogued as COSV57527836; called by muse, mutect2, varscan2
- CEP89 | c.730A>G p.K244E | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV59861916; called by muse, mutect2, varscan2
- CFAP299 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63870358; called by muse, mutect2, varscan2
- CLTCL1 | c.771G>C p.Q257H | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV54224696, COSV54235518; called by muse, mutect2, varscan2
- COL11A2 | c.5171G>A p.R1724Q (on ENST00000341947 / NM_080680.3; = p.R1617Q on NM_080679.2) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs192022847, COSV59493388; called by muse, mutect2, varscan2
- COQ6 | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53177840; called by muse, mutect2, varscan2
- COQ6 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV53177849; called by muse, mutect2, varscan2
- CPXM2 | c.1478C>T p.T493M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs143241838; called by muse, mutect2, varscan2
- CST8 | c.171C>G p.N57K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55670443; called by muse, mutect2, varscan2
- CYB5R1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV61850822; called by muse, varscan2
- DCDC1 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV60833593; called by muse, mutect2, varscan2
- DNAH9 | c.12053C>T p.P4018L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52332823; called by muse, mutect2, varscan2
- DNAJC16 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV65435592; called by muse, mutect2, varscan2
- DPM1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV54865512; called by muse, mutect2, varscan2
- EGFLAM | c.2582G>C p.R861T (on ENST00000354891 / NM_001205301.2; = p.R853T on NM_152403.4) | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV59292810, COSV59303467; called by muse, mutect2
- EMP2 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63995582, COSV63996467; called by muse, mutect2, varscan2
- EPHX1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.139); catalogued as COSV55298541; called by muse, mutect2
- ESRP1 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64407649; called by muse, mutect2, varscan2
- FAT4 | c.4604T>G p.L1535R | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs1359875187, COSV67881015; called by muse, mutect2, varscan2
- FRMD8 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV53683190; called by muse, mutect2, varscan2
- FSTL5 | c.111G>C p.M37I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV60180406, COSV60188710; called by muse, mutect2, varscan2
- FZD10 | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV57472049; called by muse, mutect2
- GEMIN5 | c.3104G>C p.R1035T | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs1354599147, COSV53557843; called by muse, mutect2, varscan2
- GLG1 | c.1501C>T p.R501* | Nonsense Mutation (SNP) | VAF 92/158 reads (58%) | catalogued as COSV52666190; called by muse, varscan2
- GLIPR1 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV56989679; called by muse, mutect2, varscan2
- GNL1 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV64835043, COSV64835300; called by muse, mutect2, varscan2
- GUCY2C | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53786566; called by muse, mutect2, varscan2
- HELB | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV56072017, COSV56072042; called by muse, mutect2, varscan2
- HIVEP3 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV56009317; called by muse, mutect2, varscan2
- HOOK1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV64617702; called by muse, mutect2, varscan2
- IKBKB | c.90C>G p.I30M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as COSV60595688; called by muse, varscan2
- INSIG1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.103); catalogued as COSV60919643, COSV60921239; called by muse, mutect2, varscan2
- ITGAL | c.626C>G p.S209* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100776027, COSV100776138; called by muse, mutect2, varscan2
- IWS1 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV54866354, COSV54867015, COSV99767403; called by muse, mutect2, varscan2
- KIAA1109 | c.2694C>G p.F898L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52661824, COSV99147054; called by muse, mutect2, varscan2
- KIF24 | c.3127G>C p.E1043Q | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV52657208; called by muse, mutect2, varscan2
- KIRREL1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs761300909, COSV63285186; called by muse, mutect2, varscan2
- MAPRE2 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55817228; called by muse, mutect2, varscan2
- MBOAT2 | c.1312A>G p.I438V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60007408; called by muse, mutect2, varscan2
- MEX3D | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1201143366, COSV66311681; called by muse, mutect2, varscan2
- MS4A3 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs780015751, COSV53934738; called by muse, mutect2, varscan2
- MYH14 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs138001307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH2 | c.3491C>T p.S1164L | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.347); catalogued as COSV55431167; called by muse, mutect2, varscan2
- MYO3B | c.3619G>A p.A1207T | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs766640832, COSV58693730; called by muse, mutect2, varscan2
- MYO5C | c.3244C>G p.Q1082E | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV55902343; called by muse, mutect2, varscan2
- NEDD9 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.191); catalogued as COSV101053405, COSV65158491; called by muse, mutect2, varscan2
- NLRP13 | c.1432G>C p.G478R | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.521); catalogued as COSV61619767; called by muse, mutect2
- NLRP7 | c.2764C>T p.L922F (on ENST00000340844 / NM_206828.3; = p.L894F on NM_139176.3) | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV60170769; called by muse, mutect2, varscan2
- NR5A2 | c.491G>A p.G164E (on ENST00000367362 / NM_205860.3; = p.G118E on NM_003822.5) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52644821; called by muse, mutect2, varscan2
- NUDT16 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.554); catalogued as rs1230878972, COSV63248141, COSV63248711; called by muse, mutect2, varscan2
- NXPE3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs746081450, COSV56288684, COSV99839742; called by muse, mutect2, varscan2
- OR8I2 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV56166511; called by muse, mutect2, varscan2
- PAK3 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.608); catalogued as COSV53270129; called by muse, mutect2, varscan2
- PCDHGA3 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV53895418, COSV53988497; called by muse, mutect2, varscan2
- PHF1 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.048); catalogued as COSV65702451; called by muse, mutect2, varscan2
- PKD1 | c.12488C>G p.S4163C (on ENST00000262304 / NM_001009944.3; = p.S4162C on NM_000296.4) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51910266; called by muse, mutect2, varscan2
- PNP | c.819G>C p.Q273H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100829006, COSV64091722; called by muse, mutect2, varscan2
- PPFIBP1 | c.2545A>G p.M849V (on ENST00000318304 / NM_177444.3; = p.M843V on NM_003622.4) | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV57287360; called by muse, mutect2, varscan2
- PPP1R10 | c.2745C>G p.F915L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV64738415; called by muse, mutect2, varscan2
- PPRC1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1017509149, COSV53382862; called by muse, mutect2, varscan2
- PRDM11 | c.421G>A p.D141N (on ENST00000530656 / NM_001359633.1; = p.D107N on NM_001256695.1) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.175); catalogued as COSV55437269; called by muse, mutect2, varscan2
- PRDM4 | c.2108A>G p.K703R | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV57304375; called by muse, mutect2, varscan2
- PREX1 | c.2705G>A p.R902K | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1292959583, COSV64247657; called by muse, mutect2, varscan2
- PRRC2C | c.193C>G p.L65V (on ENST00000367742; = p.L63V on NM_015172.4) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV58900649, COSV99056972; called by muse, mutect2, varscan2
- RAB1B | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 24/154 reads (16%) | catalogued as COSV100270613, COSV100270620, COSV57584627; called by muse, mutect2, varscan2
- RAB20 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1268779870, COSV57439607; called by muse, mutect2, varscan2
- RBAK | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1467860618, COSV62330755; called by muse, mutect2, varscan2
- RBPJL | c.1371G>A p.M457I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs201694042, COSV59212588; called by muse, mutect2, varscan2
- RHOB | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV55355325, COSV55355553, COSV55357224; called by muse, mutect2, varscan2
- RNF141 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.831); catalogued as COSV56416303; called by muse, mutect2, varscan2
- RNF182 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV70368635; called by muse, mutect2, varscan2
- SBF2 | c.3273G>C p.E1091D | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV56290933; called by muse, mutect2, varscan2
- SCEL | c.559C>A p.H187N | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV62992810, COSV62994568; called by muse, mutect2, varscan2
- SCG3 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV55019939; called by muse, mutect2, varscan2
- SCRIB | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs775403235, COSV57581955; called by muse, mutect2, varscan2
- SF1 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as COSV57111179; called by muse, mutect2, varscan2
- SH3PXD2A | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV60115503; called by muse, mutect2, varscan2
- SLC29A1 | c.312G>A p.Q104= | Splice Region (SNP) | VAF 11/40 reads (28%) | catalogued as COSV57577231; called by muse, mutect2, varscan2
- SLC37A3 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as COSV58262609; called by muse, mutect2, varscan2
- SMARCD1 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV67412913; called by muse, mutect2, varscan2
- SPIDR | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV52369006, COSV99033812; called by muse, mutect2, varscan2
- STK38 | c.992_1000del p.Y331_V334delinsL | In Frame Del (DEL) | VAF 17/99 reads (17%) | catalogued as COSV57707444; called by mutect2, pindel, varscan2
- TCF12 | c.1355G>C p.G452A | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as COSV51003332; called by muse, mutect2, varscan2
- TEFM | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58971861; called by muse, mutect2, varscan2
- TIGD7 | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV99239775; called by muse, mutect2
- TLR3 | c.2530C>A p.L844M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV57167328; called by muse, mutect2, varscan2
- TMED4 | c.359G>T p.R120M | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56941248; called by muse, mutect2, varscan2
- TMEM207 | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV61561337; called by muse, mutect2, varscan2
- TMEM59L | c.333T>G p.Y111* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99450085; called by mutect2, varscan2
- TMEM8B | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV65075601, COSV65077348; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TSC1 | c.574T>C p.Y192H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786202831, COSV53763455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSR1 | c.12C>G p.H4Q | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1482313991, COSV52155664; called by muse, mutect2, varscan2
- TTN | c.32797G>A p.E10933K (on ENST00000591111; = p.E10006K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | PolyPhen benign (0.269); catalogued as COSV59875855, COSV60002238; called by muse, mutect2, varscan2
- TUBG2 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs1267395455, COSV52216640; called by muse, mutect2, varscan2
- UBE2D1 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.948); catalogued as COSV64218092, COSV64218731; called by muse, mutect2, varscan2
- USF3 | c.3923C>G p.P1308R | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as COSV57069569; called by muse, mutect2, varscan2
- VPS13C | c.5396C>G p.S1799C (on ENST00000644861 / NM_020821.3; = p.S1756C on NM_017684.5) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV51120565; called by muse, mutect2, varscan2
- WDR17 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54567701; called by muse, mutect2, varscan2
- WDR19 | c.420G>C p.K140N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV56461509; called by muse, mutect2, varscan2
- WSCD2 | c.1629C>G p.I543M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1397503367, COSV54577585; called by muse, mutect2, varscan2
- XIRP2 | c.5212C>A p.L1738M (on ENST00000628543; = p.L1913M on NM_152381.6) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV54743712, COSV99740190; called by muse, mutect2
- ZFHX4 | c.10807G>C p.D3603H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51478806, COSV99259414; called by muse, mutect2, varscan2
- ZNF148 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.737); catalogued as COSV62302057; called by muse, mutect2, varscan2
- ZNF536 | c.2398C>T p.R800* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as rs774748439, COSV62826109; called by muse, mutect2, varscan2
- ZNF777 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV56096117; called by muse, mutect2, varscan2
- CENPF | c.3139del p.Q1047Rfs*7 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- ZNHIT6 | c.1221del p.I407Mfs*8 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- ANKDD1A | c.111G>A p.R37= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100132621; called by muse, mutect2
- ARHGAP39 | c.2868G>A p.L956= (on ENST00000276826 / NM_001308208.2; = p.L987= on NM_025251.2) | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99430551; called by muse, mutect2
- ATP13A5 | c.1494C>G p.L498= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV60865453; called by muse, mutect2
- C2orf76 | c.124C>T p.L42= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV58345481; called by muse, mutect2, varscan2
- CALHM1 | c.1023C>G p.T341= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1342767196, COSV53297096, COSV99588311; called by muse, mutect2, varscan2
- CCAR1 | c.3216G>A p.L1072= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs1326070983, COSV56266950; called by muse, mutect2, varscan2
- CDH23 | c.2649C>G p.L883= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as COSV54923741; called by muse, mutect2, varscan2
- CILP | c.3258G>A p.T1086= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs781558209, COSV56021730; called by muse, mutect2, varscan2
- CNTN2 | c.60C>G p.V20= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV59347965; called by muse, mutect2, varscan2
- CYFIP1 | c.30G>A p.A10= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs34148834; called by muse, mutect2, varscan2
- CYP2S1 | c.777G>A p.L259= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs769905212, COSV100027563, COSV59504946; called by muse, mutect2, varscan2
- DIRAS3 | c.42G>T p.L14= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV63970419; called by muse, mutect2, varscan2
- EVPL | c.3285G>C p.L1095= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs1038473817, COSV56907172; called by muse, mutect2, varscan2
- FIBCD1 | c.951C>G p.L317= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs764246848, COSV53392363; called by muse, mutect2, varscan2
- GDPD5 | c.276G>A p.V92= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100409156; called by muse, mutect2
- HMCN1 | c.15570T>C p.C5190= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs1460536552, COSV54875237; called by muse, mutect2, varscan2
- KHK | c.303C>T p.I101= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV53153028; called by muse, mutect2, varscan2
- MYLK4 | c.1011C>T p.F337= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV51138160; called by muse, mutect2, varscan2
- OR10H1 | c.550C>T p.L184= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as rs867703687, COSV58470625; called by muse, mutect2, varscan2
- OR4D11 | c.264G>A p.K88= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV57584548, COSV57587118; called by muse, mutect2, varscan2
- PCDHGA1 | c.696G>T p.V232= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV65294835; called by muse, mutect2, varscan2
- PCDHGA3 | c.606T>G p.R202= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV53895432; called by muse, mutect2, varscan2
- PIP4P1 | c.534G>A p.K178= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs759950378, COSV51656918; called by muse, mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PTPRA | c.1890G>C p.V630= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV53778108, COSV53788684; called by muse, mutect2, varscan2
- RHCG | c.1059C>T p.I353= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs146417060, COSV51519254; called by muse, mutect2, varscan2
- SDK2 | c.2439C>T p.N813= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs148179574; called by mutect2, varscan2
- SPTBN4 | c.1044C>T p.L348= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1330547248, COSV58943222; called by muse, mutect2, varscan2
- ZNF699 | c.780C>T p.F260= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV58024700; called by muse, mutect2, varscan2
- ADA | c.*2G>C | 3'UTR (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100596095; called by muse, mutect2, varscan2
- ARHGEF4 | c.1921+27C>T | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs996913987, COSV58117517; called by muse, mutect2, varscan2
- C8orf86 | n.799C>T | RNA (SNP) | VAF 23/164 reads (14%) | catalogued as COSV63935089; called by muse, mutect2, varscan2
- EFCAB10 | c.*17C>T | 3'UTR (SNP) | VAF 30/83 reads (36%) | catalogued as COSV57557218; called by muse, mutect2, varscan2
- HNMT | c.190+11147A>G | Intron (SNP) | VAF 29/115 reads (25%) | catalogued as COSV54505871; called by muse, mutect2, varscan2
- LIN9 | c.244+462G>A | Intron (SNP) | VAF 20/83 reads (24%) | catalogued as rs1378451566, COSV60243702; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 12/37 reads (32%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TRIM41 | c.*187C>T | 3'UTR (SNP) | VAF 21/50 reads (42%) | catalogued as rs151121296, COSV100163032; called by muse, mutect2, varscan2
